Somatic mutation profile of tumor specimen TARGET-10-PARDXS-09A (aliquot TARGET-10-PARDXS-09A-01D) from TARGET case TARGET-10-PARDXS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,347 days).
Specimen TARGET-10-PARDXS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a96b6fdb-9bcd-498a-9752-a62000e04992.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDXS-14A (Bone Marrow Normal), aliquot TARGET-10-PARDXS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b320f1dd-906c-404e-9283-a419ee1948da

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 5'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); catalogued as rs776520067; called by muse, mutect2, varscan2
- GRM8 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs201160740, COSV58870928; called by muse, mutect2, varscan2
- LTF | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs142920270; called by muse, mutect2, varscan2
- MORN1 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as rs144096006; called by muse, varscan2
- OLFM3 | c.260G>A p.R87H (on ENST00000338858 / NM_001288821.1; = p.R67H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs748816968, COSV58801462; called by muse, mutect2, varscan2
- VIP | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV100923969; called by muse, mutect2, varscan2
- DDB1 | c.2248A>G p.T750A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN2 | c.8451C>A p.H2817Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ACLY | c.2742G>A p.A914= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs369879357; called by muse, mutect2, varscan2
- CACNA1D | c.3861C>T p.S1287= (on ENST00000350061 / NM_001128840.3; = p.S1307= on NM_000720.4) | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs999494600, COSV55445126; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO15B | c.3870T>A p.P1290= | Silent (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- CFI | c.-113A>G | 5'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- GOT1L1 | c.116-62A>T | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- MIR96 | n.5C>T | RNA (SNP) | VAF 28/53 reads (53%) | catalogued as rs762205680; called by muse, mutect2, varscan2
